Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A8P0, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A8P0-01A (Primary Tumor).

[page 1 of 5]
Referring Physician:

DOB: Age: Gender: M

Ref#: Hosp#: Provider Group :

Date of Service: Date Received: Outpatient Case #:
Room: Bed: Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

ICD-O-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreas head c25.0
JW 4/7/14

A. GALLBLADDER, CHOLECYSTECTOMY:

- Mild chronic cholecystitis.

B. PANCREAS, STOMACH, DUODENUM, WHIPPLE PROCEDURE:

- Invasive ductal adenocarcinoma, well-differentiated.
- Tumor size: 3.1 cm.
- Tumor invades into peripancreatic soft tissue.
- Ten of nineteen lymph nodes POSITIVE for metastatic adenocarcinoma (10/19).
- Surgical margins negative.

C. LYMPH NODES, LEFT RENAL VEIN AREA, REGIONAL RESECTION:

- Four lymph nodes POSITIVE for metastatic adenocarcinoma (4/4).

D. LYMPH NODE, COMMON BILE DUCT, BIOPSY:

- One lymph node POSITIVE for metastatic adenocarcinoma (1/1).

PATHOLOGIC TUMOR STAGING SYNOPSIS (EXOCRINE PANCREAS):

Type and grade: Adenocarcinoma, well-differentiated.

Primary tumor: pT3.

Regional lymph nodes: pN1.

Distant metastasis: N/A.

Pathologic stage: IIB.

Lymphovascular invasion: Present.

Margin status: R0, negative.

Exocrine Pancreas Tumor Staging Information

(AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, June 2012)

Case #:

Printed:

Page 1

This report continues... (FINAL)

[page 2 of 5]
Patient:

Case #:

Specimen:	Whipple specimen.
Procedure:	Whipple procedure.
Tumor site:	Head of pancreas.
Tumor size:	3.1 cm.
Histologic type:	Adenocarcinoma.
Histologic grade:	G1, well-differentiated.
Microscopic tumor extension:	Tumor extends into peripancreatic soft tissue.
Margins:	R0, negative, tumor 0.1 cm from posterior margin, 1.2 cm from pancreatic margin, distant from gastric and duodenal margins.
Treatment effect:	N/A.
Lymph-vascular invasion:	Present.
Perineural invasion:	Not identified.
Lymph nodes:	Fifteen of twenty-four lymph nodes positive for metastatic carcinoma.
Pathologic Staging:	
Primary tumor	pT3.
Regional lymph nodes	pN1.
Distant metastasis	N/A.
Pathologic stage	IIB.

Signed by

Source of Specimen:

- A. Gallbladder
- B. Whipple
- C. Lymph node; Left renal vein nodes
- D. Lymph node; Common bile duct node

Clinical History/Operative Dx:

Neoplasm of the head of the pancreas.

Intraoperative Diagnosis:

B. (Frozen section x3) Whipple procedure:

Case #:

Printed:

Page 2

This report continues... (FINAL)

MR No. -

atient Name

[page 3 of 5]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

- Bile duct and pancreatic margin negative.
- Metastatic adenocarcinoma in lymph node.

(Performed by

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. Part A designated gallbladder. Received in formalin is an intact gallbladder, 8.7 x 2.6 x 2.3 cm. The serosa is glistening slightly fatty tan-green. The cystic duct margin demonstrates a 1 mm lumen that is probe patent. The wall is 0.1 cm, and the lumen contains a copious amount of viscous dark green bile with a few minute particulate and no well formed calculi. The mucosa is velvety, dark green without grossly unusual areas of change suggestive of neoplasia. No grossly unusual areas of change are suggestive of neoplasia. Representative sections are submitted in A1 and A2.

B. Initially received in the fresh state for frozen section evaluation is a generous portion of tissue consistent with a Whipple procedure specimen. The Whipple consists of a generous portion of the antrum of stomach, 11.0 cm along the greater, 7.2 cm along the lesser curvature, 5.6 cm in diameter at the proximal margin of resection; the small bowel length is 22.5 cm, 2.5 cm in diameter at the distal margin of resection and 3.2 cm in diameter near the head of the pancreas; the pancreas is up to 4.8 cm in length, 4.4 cm superior-inferior, and 4.0 cm posterior-anterior. The common bile duct extends 0.5 cm and 0.8 cm in diameter, with a 0.5 cm patent lumen. A stent protrudes from the bile duct margin. A long silk suture marks the distal pancreatic surgical margin and demonstrates a 0.25 cm diameter duct that is probe patent. The pancreatic surfaces/margins are differentially inked as follows: anterior - yellow, superior - blue, inferior - green, posterior - black and the pancreatic notch marked red.

The stomach is opened along the greater curvature and the length of the small bowel is opened revealing the ampulla of Vater oriented 7.0 cm distal to the pylorus, slightly raised and granular, dusky red, over an area of 1.0 x 0.7 cm. The common bile duct is probe patent with the AV. The pancreatic duct inserts into the small bowel just 0.3 cm inferior to the AV (does not communicate). Sectioning through the head of the head of the pancreas reveals an ill-defined, mucinous, light gray to admixed yellow, mass lesion within the superior head of the pancreas, measuring upwards of 3.1 x 2.5 x 2.0 cm. Grossly, the tumor is 1.2 cm away from the distal pancreatic margin. The tumor is within 0.1 cm of the superior margin, 0.1 cm of the posterior (including pancreatic notch), 1.7 cm from inferior, and 0.3 cm from anterior. Near the CBD, there is a palpable, firm lymph node that is sectioned, revealing a mucinous, dense, light gray appearance. The bile duct margin, pancreatic margin and lymph node are submitted/represented for frozen section evaluation. A representative portion of the grossly positive lymph node and possible tumor within the head of the pancreas is submitted for studies - tumor bank. The tumor partially abuts the small bowel wall along the superior-anterior head of the pancreas with a single 0.2 cm focus of involvement through the small bowel muscularis (B7). The tumor partially abuts the CBD, however, the length of the lumen is wrinkled and light tan without gross invasive tumor. The grossly uninvolved pancreas is semi-congested-inflamed, lobular, yellow-tan parenchyma, with transient areas of induration-density. Examination of the peripancreatic fat reveals nineteen lymph nodes ranging from 0.3 cm to 2.0 x 1.7 x 0.8 cm each. The presence of invasive tumor within the fat makes lymph node identification difficult.

Case #:

Page 3

Printed:

This report continues... (FINAL)

MR No. -

Patient Name -

[page 4 of 5]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

The gastric mucosa is severely congested, dusky, deep red without discrete ulceration, polypoid changes or induration of the gastric wall. Within 8.5 cm of the distal small bowel margin of resection, the mucosa is markedly congested, dusky red, abruptly transitioning to a light tan prominent circular plica through the remainder of the proximal length. No lesions appreciated. Examination of the scant amount of perigastric fat along the greater curvature does not reveal lymph node content. Examination of the fat associated with the lesser curvature reveals softened, red-tan lymph nodes ranging from 0.3 to 0.4 cm.

Cassette summary:

- B1) bile duct margin, FS,
- B2) pancreatic margin, FS,
- B3) lymph node near bile duct margin, FS,
- B4-B5) ampulla of Vater including adjacent pancreatic duct relationship - head of pancreas,
- B6) pancreatic duct - small bowel relationship,
- B7) small bowel, head of pancreas, invasive tumor,
- B8) tumor, common bile duct within head of pancreas,
- B9) distal end of pancreas, margin trimmed for frozen section now marked orange and tumor relationship,
- B10) anterior pancreas, possible lymph node content, tumor,
- B11) posterior pancreas, near distal margin of resection,
- B12) posterior pancreas, uncinate aspect, tumor within fat,
- B13-B14) superior pancreas, tumor,
- B15) mesenteric groove/pancreatic notch, tumor,
- B16) inferior pancreas, possible lymph node content,
- B17) large lymph node formerly sampled for FS evaluation, involved with tumor,
- B18) uninvolved pancreas,
- B19) anterior and posterior, proximal gastric margin of resection,
- B20) distal small bowel margin of resection,
- B21) four lymph nodes, perigastric fat,
- B22) five lymph nodes, peripancreatic,
- B23) five lymph nodes, peripancreatic,
- B24) two lymph nodes, bisected, one marked orange, peripancreatic,
- B25) two lymph nodes, bisected, one marked orange, pancreatic,
- B26) two lymph nodes, bisected, one marked orange, pancreatic,
- B27) large lymph node, bisected, pancreatic,
- B28) single lymph node, bisected, pancreatic
- B29) grossly positive node, sectioned and submitted, pancreatic.

C. Part C designated left renal vein nodes. Received in formalin is a 8 gram portion of yellow-tan fatty soft tissue, 3.6 x 2.8 x 2.3 cm. Examination reveals four lymph nodes ranging from 0.5 cm - 2.1 x 1.8 cm each. The largest node may represent multiple adherent-matted lymph nodes. Lymph node tissue is entirely submitted for microscopic evaluation.

Cassette summary:

- C1) single lymph node,
- C2) two lymph nodes bisected, one marked green,

Case #

Printed:

Page 4

This report continues... (FINAL)

MR No.

[page 5 of 5]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

C3-C5) largest lymph node. ■

D. Part D designated common bile duct node. Received in formalin is a yellow-tan portion of fatty soft tissue 1.7 x 1.3 x 0.4 cm. Surgical clips are present, removed and the tissue was examined revealing two distinct lymph nodes 0.3 and 0.4 cm each. The two lymph nodes including the residual fat are submitted together between two sponges in D1. ■

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #:

Printed:

MR No. -

Source: NCI Genomic Data Commons file c02a0b6c-8918-4918-915e-7d73f96a24de (TCGA-HZ-A8P0.8D96A131-D451-4057-BDA6-2652DB076538.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).